MMRF case MMRF_1547 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/34e1585c-8b4e-4dbd-a637-aef6bb22dcc6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,811 days); ISS stage: II; Days to last known disease status: 1,243 days (3.4 years); Days to last follow up: 1,243 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 193 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 642 days (1.8 years); Days to treatment end: 865 days (2.4 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 892 days (2.4 years); Days to treatment end: 1,222 days (3.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,243.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.927 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 24.2 mg/dL; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 4.8 g/dL; Glucose 6.33 mmol/L.
- Day 85 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7 mg/dL; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 4.8 g/dL; Glucose 4.62 mmol/L.
- Day 158 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.68 mg/dL; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 4.9 g/dL; Glucose 6.44 mmol/L.
- Day 212 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.89 mg/dL; Hemoglobin 5.95 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Glucose 5.5 mmol/L.
- Day 297 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.92 mg/dL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.1 g/dL; Glucose 5.06 mmol/L.
- Day 428 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.976 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 4.9 g/dL; Glucose 4.46 mmol/L.
- Day 536 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 5.2 g/dL; Glucose 4.95 mmol/L.
- Day 604 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.7 g/dL; Glucose 7.04 mmol/L.
- Day 697 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.4 g/dL; Glucose 5.56 mmol/L.
- Day 795 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 3.69 mmol/L.
- Day 900 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Glucose 4.46 mmol/L.
- Day 998 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.857 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 5.8 g/dL; Glucose 4.07 mmol/L.
- Day 1,059 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 1,152 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.827 mg/dL; Immunoglobulin G 6.44 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 3.63 mmol/L.
- Day 1,240 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -9: Weight: 68 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1547_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1547_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
